CCDI case PBBRLR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/49976aab-fda8-4be6-8498-96d447a91f4f

Demographics
Sex at birth: female; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Sclerosing stromal tumor: ICD-O-3 morphology code: 8602/0; Tissue or organ of origin: Fallopian tube; Age at diagnosis: 14.3 years (5,217 days).

Biospecimens (3 samples)
- Sample 0DFRTH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFRTI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DFRTJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
